Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A17Z, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A17Z-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex: years Male
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

M57. Had a large melanoma arising in giant congenital naevus on the (L) lower back (core bx 2.5.08, followed by excision on 23.5.08 -> 60 x 60 x 35mm dia tumour mass, level V, mit 9/mm2, surgical margin on the melanoma was 0.7mm

* Presented to ED on having self-palpated a large (L) groin node, with confirming melanoma showed the inguinal mass to be glucose-avid, but identified no further lesions.

Operation: Radical left groin dissection.

Specimen: Radical (L) groin dissection.

MACROSCOPIC DESCRIPTION

"LEFT GROIN CONTENTS - STITCH UPPER". An irregular piece of fibrofatty tissue 220 x 85 x 37mm partially covered by a skin ellipse 195 x 21mm. Staples side anteriorly inked blue and posteriorly inked black.

A well-circumscribed dark-brown nodule is present measuring 35 x 35 x 27mm. A 2mm slice taken for tumour banking. Remainder tissue apart from the largest nodule, contains multiple lymph nodes measuring up to 22mm across.

A - D. One full face of the dark brown nodule

E. Four lymph nodes

F. One lymph node bisected

G. One lymph node bisected

H - J. One lymph node bisected

K. Four lymph nodes

L. One lymph node bisected

M. One lymph node bisected

N - P. One lymph node bisected

Q. Four lymph nodes

R. One lymph node bisected

S. One lymph node bisected.

MICROSCOPIC REPORT

The (L) groin dissection contains **metastatic melanoma** involving 2 (of 20) nodes.

The tumour deposits are 33mm dia and 0.6mm dia (blocks 1A-D; and 1S).

The large deposit has extensive tumour necrosis, and there is **extranodal extension** (1D).

The small deposit (1S) is an isolated intranodal micrometastasis.

Cytologically the melanoma has a small epithelioid/naevoid cytomorphology, moderate patchy cytoplasmic pigment, mitoses 15/mm2. No obvious TILs response, and the inflammation seen in the large deposit is likely to be directed against the necrosis.

Surgical margins appear clear of the involved node (1C).

SUMMARY

(L) groin dissection - **Metastatic MALIGNANT MELANOMA (2/20).**

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

Includes a 33mm dia deposit, with extranodal extension.

REPORTED BY: Dr (

Printed:

Source: NCI Genomic Data Commons file a57675c5-4642-472c-a5c6-48b288194ed9 (TCGA-EE-A17Z.837DDC06-26E8-44F2-BE68-62A81ED42795.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).